Somatic mutation profile of tumor specimen TCGA-EM-A3FO-01A (aliquot TCGA-EM-A3FO-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.7 years (14,864 days).
Specimen TCGA-EM-A3FO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99fb94c3-e904-4251-96fc-c23b9139dcf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FO-10A (Blood Derived Normal), aliquot TCGA-EM-A3FO-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4d07678-0106-4d0f-9be4-36d351d6578c

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ENPP1 | c.324C>A p.C108* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV62930287; called by muse, mutect2, varscan2
- PIK3R5 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as rs376420068, COSV52650774; called by muse, mutect2, varscan2
- PNMA8B | c.839T>G p.L280W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV66537326; called by muse, mutect2
